Somatic mutation profile of tumor specimen TARGET-10-PARPET-09A (aliquot TARGET-10-PARPET-09A-01D) from TARGET case TARGET-10-PARPET, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,811 days).
Specimen TARGET-10-PARPET-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a2680e0-4aaa-45d6-b9f9-19943affbfe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPET-10A (Blood Derived Normal), aliquot TARGET-10-PARPET-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/124ca872-7a29-4f6e-b5ae-d966f88c7330

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.673C>T p.R225* (on ENST00000332070 / NM_032458.3; = p.R226* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 47/103 reads (46%) | catalogued as rs1556018932, COSV59699600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs762630043, COSV55781303, COSV55782439; called by muse, mutect2, varscan2
- CDC20B | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57052487; called by muse, mutect2, varscan2
- HSPG2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs748179999, COSV65969970; called by muse, mutect2, varscan2
- L3MBTL1 | c.955C>A p.Q319K (on ENST00000418998 / NM_001377303.1; = p.Q229K on NM_015478.7) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64228494; called by muse, mutect2, varscan2
- LEF1 | c.854dup p.H286Afs*2 | Frame Shift Ins (INS) | VAF 47/104 reads (45%) | catalogued as COSV54467438; called by mutect2, pindel*, varscan2*
- PTGFR | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66115059; called by muse, mutect2, varscan2
- UPK3B | c.685C>T p.H229Y (on ENST00000257632; = p.V200= on NM_001347684.2) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV57536633; called by muse, mutect2, varscan2
- COL1A2 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DGKK | c.3471T>C p.D1157= | Silent (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- OR4F15 | c.273C>A p.A91= | Silent (SNP) | VAF 93/200 reads (47%) | called by muse, mutect2, varscan2
- TES | c.6C>T p.D2= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- TFAP2D | c.315C>A p.I105= | Silent (SNP) | VAF 86/191 reads (45%) | catalogued as COSV50408127; called by muse, mutect2, varscan2
- TMEM132D | c.771C>T p.I257= | Silent (SNP) | VAF 49/103 reads (48%) | catalogued as rs755152475, COSV70592774; called by muse, mutect2, varscan2
- IFNL2 | c.*15A>G | 3'UTR (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
